HCMI case HCM-BROD-0140-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4f86f0ad-83af-45fb-8579-16cf09f4de2f

Demographics
Sex at birth: female; Race: white; Year of birth: 1933; Vital status: Dead; Days to death: 28 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 83.5 years (30,481 days); AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior treatment: No.
   Pathology details: Additional pathology findings: Intestinal metaplasia.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Days to follow up: 28 days; Disease response: Stable Disease; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: GERD.
- Timepoint category: Prior to Diagnosis; Risk factors: Intestinal Metaplasia.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples)
- Sample HCM-BROD-0140-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-BROD-0140-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 19.
